CCDI case PBCEVK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9f5bd075-c9b9-4ed7-9d15-031b1399e345

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 6.7 years (2,429 days).

Biospecimens (3 samples)
- Sample 0DQC1V: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQC22: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQC26: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
